Somatic mutation profile of tumor specimen BA2517D (aliquot aq-BA2517D) from BEATAML1.0 case 2104, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 45.7 years (16,703 days).
Specimen BA2517D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cf5c320-f252-46eb-b1ea-e26bd9bfc9dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2819D (Solid Tissue Normal), aliquot aq-BA2819D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab585ffe-ba81-45bf-b47e-eee87ac5c7d9

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Frame Shift Ins 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA2 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 51/109 reads (47%) | catalogued as rs387906632, CM117933, COSV62007611; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EZH2 | c.1598C>T p.S533L (on ENST00000460911 / NM_001203247.2; = p.S538L on NM_004456.5) | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV57446300; called by muse, mutect2, varscan2
- GRM3 | c.428C>A p.A143E | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV64474153; called by muse, mutect2
- HYDIN | c.4822G>A p.E1608K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs1244006572; called by mutect2, varscan2
- OR4K13 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150686832, COSV100237803, COSV59859719; called by muse, mutect2, varscan2
- SFXN1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as rs1201704038; called by muse, varscan2
- ZNF687 | c.2815dup p.R939Pfs*36 | Frame Shift Ins (INS) | VAF 23/88 reads (26%) | catalogued as rs749403447; called by mutect2, varscan2
- CBY3 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- CSMD2 | c.9239G>A p.R3080K | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LIME1 | c.674C>A p.A225E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.053); called by muse, mutect2
- ADRA1D | c.60A>G p.A20= | Silent (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- KIF13A | c.4227A>G p.P1409= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as rs1180737667; called by muse, mutect2, varscan2
- TANC1 | c.2499G>A p.L833= | Silent (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2
- TMEM88 | c.355C>T p.L119= | Silent (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- ZFHX3 | c.-897+3591G>A | Intron (SNP) | VAF 39/79 reads (49%) | catalogued as rs1028324630; called by muse, mutect2, varscan2
